Gene-level copy-number profile of tumor specimen C3L-08974-01 from CPTAC case C3L-08974, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.7 years (29,859 days).
Specimen C3L-08974-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 89147366-6cfe-4c17-af71-e8e91692cfed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08974-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/0809145e-d128-41f5-81c3-fb50a739eb84

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 159; copy number 2: 57,971; copy number 3: 49; copy number 4: 123; copy number 6: 33; copy number 9: 67.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:1,296,034–4,994,972, 33 genes, copy number 6 (within-gene range 4–6): AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1.
- chr8:10,054,292–12,071,747, 67 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 159. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
